Somatic mutation profile of tumor specimen TCGA-B4-5832-01A (aliquot TCGA-B4-5832-01A-11D-1669-08) from TCGA case TCGA-B4-5832, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.2 years (23,806 days).
Specimen TCGA-B4-5832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bc2e5e3-68f1-4328-a138-43dce7742b37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5832-10A (Blood Derived Normal), aliquot TCGA-B4-5832-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f4e7203-2af2-42ad-a324-825bd0cbee10

The open-access MAF lists 77 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Frame Shift Del 6, Splice Site 2, Nonstop Mutation 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5930C>G p.T1977R | Missense Mutation (SNP) | VAF 46/179 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63868784, COSV63869673, COSV63869920; called by muse, mutect2, varscan2
- VHL | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM951276, CM952019, COSV56546515, COSV56547374, COSV56564109; called by muse, mutect2
- ASB8 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV58351963; called by muse, mutect2
- ATM | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV99590816; called by mutect2, varscan2
- BSN | c.10462A>G p.M3488V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1348418498, COSV56527829; called by muse, varscan2
- C12orf50 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53899041; called by muse, mutect2
- CCDC158 | c.2396A>G p.E799G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV66357227; called by muse, mutect2, varscan2
- CCDC88A | c.2292A>C p.E764D | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55070203; called by muse, mutect2, varscan2
- CDYL | c.859T>C p.S287P (on ENST00000328908 / NM_001368125.1; = p.S233P on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59359133; called by muse, mutect2, varscan2
- CFTR | c.3467T>G p.L1156W | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV50104237; called by muse, mutect2, varscan2
- CLDN15 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1458632195, COSV57659745; called by muse, mutect2
- COL1A2 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51960509, COSV51967824; called by muse, mutect2, varscan2
- CREB5 | c.1210G>C p.E404Q (on ENST00000357727 / NM_182898.4; = p.E397Q on NM_004904.3) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100745568, COSV63228774; called by muse, mutect2, varscan2
- CSMD3 | c.2271C>A p.S757R (on ENST00000297405 / NM_001363185.1; = p.S653R on NM_052900.3) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52322338; called by muse, mutect2, varscan2
- DMXL1 | c.8263A>T p.T2755S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.135); catalogued as COSV60720993; called by muse, mutect2
- EMB | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV57484612; called by muse, mutect2, varscan2
- ERBB4 | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as rs763374665, COSV53588897; called by muse, mutect2, varscan2
- FLT1 | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as COSV56743394; called by muse, mutect2, varscan2
- GABRA2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62920076; called by muse, mutect2
- GATA3 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as rs752977342, COSV60515966, COSV60516876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H2AC21 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100480058, COSV58613229; called by muse, mutect2, varscan2
- HNMT | c.734C>G p.T245S | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV54510413; called by muse, mutect2, varscan2
- IGSF10 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1435703016, COSV56791846; called by muse, mutect2
- KLC1 | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV55811484; called by muse, mutect2, varscan2
- MAP3K3 | c.1161A>C p.E387D | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV62281825; called by muse, mutect2
- MRC1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV58889914; called by muse, mutect2, varscan2
- NGB | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53611993; called by muse, mutect2, varscan2
- NLRP3 | c.2273T>C p.V758A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs770791406, COSV60231079; called by muse, mutect2, varscan2
- NUP160 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV65856131; called by muse, mutect2, varscan2
- NUP98 | c.4845G>T p.W1615C (on ENST00000359171 / NM_001365126.1; = p.W1598C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61438624; called by muse, mutect2, varscan2
- NXPH1 | c.160T>C p.S54P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV68319849; called by muse, mutect2
- OR1N1 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1279758090, COSV59196887; called by muse, mutect2, varscan2
- OR2T33 | c.864C>G p.Y288* | Nonsense Mutation (SNP) | VAF 33/221 reads (15%) | catalogued as rs145618749, COSV58817985; called by muse, mutect2, varscan2
- PABPC5 | c.868C>G p.R290G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV57040186, COSV57043239; called by muse, mutect2, varscan2
- PBRM1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV56269973; called by muse, mutect2, varscan2
- PTPN14 | c.1874G>T p.S625I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775645066, COSV65288085, COSV65288639; called by muse, mutect2, varscan2
- REV1 | c.3254G>A p.R1085K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51490627; called by muse, mutect2
- RHAG | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV57706357, COSV57706445; called by muse, mutect2, varscan2
- RXFP3 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV57508279; called by muse, mutect2, varscan2
- SH2D1B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765738687, COSV63392822; called by muse, mutect2, varscan2
- SLC9A6 | c.505A>C p.R169= | Splice Region (SNP) | VAF 35/73 reads (48%) | catalogued as COSV65787440, COSV65789078; called by muse, mutect2, varscan2
- TBK1 | c.1684A>C p.I562L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59158465; called by muse, mutect2, varscan2
- TJP3 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs150589606; called by muse, mutect2, varscan2
- USH2A | c.15609A>C p.*5203Yext*8 | Nonstop Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV52070692; called by muse, mutect2, varscan2
- VEGFC | c.562A>C p.I188L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV54606949; called by muse, mutect2, varscan2
- WAS | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs781917584, CD962186, COSV100939475; called by muse, mutect2
- WDR20 | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100085309; called by muse, mutect2, varscan2
- ZNF319 | c.1459A>C p.K487Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV54624006; called by muse, mutect2
- ARHGAP30 | c.2444del p.G815Efs*42 | Frame Shift Del (DEL) | VAF 27/164 reads (16%) | called by mutect2, pindel, varscan2
- CAMK2G | c.402_414+2del p.X134_splice | Splice Site (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CCDC63 | c.1214_1224del p.K405Tfs*16 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- IL17RC | c.319-9_319delinsTT p.X107_splice (on ENST00000295981 / NM_153461.4; = p.X36_splice on NM_032732.6 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 34/239 reads (14%) | called by pindel, varscan2*
- LIMCH1 | c.2864_2866dup p.D955dup | In Frame Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- LIMK1 | c.1386_1392del p.N462Kfs*57 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- MUC2 | c.1325C>G p.P442R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); called by muse, mutect2, varscan2
- OR1J1 | c.331_339del p.D111_F113del | In Frame Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2604dup p.Q869Sfs*6 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- SAMHD1 | c.161del p.L54Pfs*12 | Frame Shift Del (DEL) | VAF 53/249 reads (21%) | called by mutect2, pindel, varscan2
- TAOK3 | c.2250del p.H750Qfs*5 | Frame Shift Del (DEL) | VAF 45/265 reads (17%) | called by mutect2, pindel, varscan2
- ZNF585B | c.1015del p.S339Pfs*31 | Frame Shift Del (DEL) | VAF 43/219 reads (20%) | called by mutect2, pindel, varscan2
- ATP9A | c.369G>A p.E123= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58771969; called by muse, mutect2, varscan2
- C2CD6 | c.690C>A p.V230= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV53800660; called by muse, mutect2, varscan2
- CYP11B1 | c.336C>T p.S112= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV52830356; called by muse, mutect2, varscan2
- DOK4 | c.195C>T p.V65= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV54674405; called by muse, mutect2, varscan2
- ENPP3 | c.48C>T p.N16= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1238297182, COSV62956889; called by muse, mutect2
- ETV4 | c.363C>T p.G121= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1379773926, COSV60045246; called by muse, mutect2, varscan2
- GNAT3 | c.687C>G p.A229= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV68070172; called by muse, mutect2, varscan2
- GPR32 | c.276A>G p.S92= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV54515621; called by muse, mutect2, varscan2
- KCNH1 | c.1359G>A p.S453= (on ENST00000271751 / NM_172362.3; = p.S426= on NM_002238.4) | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs764070927, COSV55081074, COSV55104814; ClinVar: likely benign; called by muse, mutect2, varscan2
- MROH7 | c.858T>A p.S286= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV59878058; called by muse, mutect2, varscan2
- PRAMEF15 | c.960G>C p.P320= | Silent (SNP) | VAF 25/224 reads (11%) | called by muse, mutect2, varscan2
- RFX2 | c.1893C>T p.S631= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs764867079, COSV57945503; called by muse, mutect2, varscan2
- SLC7A3 | c.1224C>T p.D408= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV53229342, COSV99979274; called by muse, mutect2
- SST | c.295C>A p.R99= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as COSV55031006, COSV55031433; called by muse, mutect2
- TACC3 | c.786A>G p.G262= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1250218843, COSV57608066; called by muse, mutect2, varscan2
- UBN2 | c.2325G>A p.A775= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs528507397, COSV56035491; called by muse, mutect2, varscan2
- SSPOP | n.7599C>T | RNA (SNP) | VAF 11/44 reads (25%) | catalogued as COSV50489360; called by muse, mutect2, varscan2
